Somatic mutation profile of tumor specimen MMRF_1750_1_BM_CD138pos (aliquot MMRF_1750_1_BM_CD138pos_T1_KBS5U_K11914) from MMRF case MMRF_1750, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.2 years (25,268 days).
Specimen MMRF_1750_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a8502f7-8fb1-4af1-9dbf-362f914b0d7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1750_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1750_1_PB_Whole_C2_KBS5U_K11906; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ee80565-4361-475e-a97b-a3f778f6f7e7

The open-access MAF lists 112 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 28, Silent 17, Intron 12, Frame Shift Del 4, 3'Flank 4, 5'Flank 4, Nonsense Mutation 3, RNA 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.4351G>A p.V1451I | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.401); catalogued as rs1319919965; called by muse, mutect2, varscan2
- ADAM29 | c.974C>T p.T325I | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs1376737898; called by muse, mutect2
- ANKRD31 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.435); catalogued as COSV57163545; called by muse, mutect2, varscan2
- ANO7 | c.1336G>A p.A446T (on ENST00000274979; = p.A392T on NM_001370694.2) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs759669755; called by muse, mutect2, varscan2
- ARID1A | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 37/68 reads (54%) | catalogued as COSV61381323; called by muse, mutect2, varscan2
- DDR1 | c.2569G>A p.A857T (on ENST00000324771; = p.A820T on NM_001954.4) | Missense Mutation (SNP) | VAF 106/165 reads (64%) | SIFT tolerated (1); PolyPhen possibly damaging (0.554); catalogued as rs1447733299; called by muse, mutect2, varscan2
- EFNB1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs370690590, COSV52662805; called by muse, mutect2, varscan2
- FAM20C | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs531384573; called by muse, mutect2, varscan2
- IGHV2-70 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs373039668; called by muse, varscan2
- IMMT | c.2123A>C p.K708T | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs568826395; called by muse, mutect2, varscan2
- OR8B8 | c.212T>C p.F71S | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as COSV60144979; called by muse, mutect2
- PRR12 | c.2167C>T p.R723W (on ENST00000615927; = p.R1544W on NM_020719.3) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs987119506; called by muse, mutect2, varscan2
- RFLNB | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs782713598; called by muse, mutect2, varscan2
- SARS1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as rs767953116, COSV52320765, COSV52322995; called by muse, mutect2, varscan2
- SETD2 | c.4235_4238del p.E1412Vfs*19 | Frame Shift Del (DEL) | VAF 63/152 reads (41%) | catalogued as rs771527963; called by mutect2, pindel, varscan2
- STAB1 | c.5387G>A p.R1796Q | Missense Mutation (SNP) | VAF 225/228 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs750335748, COSV58735036; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 109/224 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54869289; called by muse, mutect2, varscan2
- TYR | c.635G>T p.R212I | Missense Mutation (SNP) | VAF 94/223 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM033051, CM100985, COSV99634717; called by muse, mutect2, varscan2
- UNC13C | c.4930G>A p.E1644K | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99522202; called by muse, mutect2, varscan2
- ZKSCAN8 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 84/135 reads (62%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs1325065114; called by muse, mutect2, varscan2
- ATP7A | c.2099T>C p.F700S | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- CCDC116 | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 135/144 reads (94%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CD40LG | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELF4 | c.38C>G p.A13G | Missense Mutation (SNP) | VAF 5/139 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2
- CNOT10 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- DICER1 | c.5109del p.L1704* | Frame Shift Del (DEL) | VAF 52/116 reads (45%) | called by mutect2, varscan2
- EVPL | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR149 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HSPA8 | c.1704_1705del p.K569Dfs*6 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | called by mutect2, pindel, varscan2
- KALRN | c.7820A>G p.Y2607C (on ENST00000360013 / NM_001024660.4; = p.Y910C on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.8658T>A p.S2886R | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MYO1F | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAA15 | c.2155+2T>A p.X719_splice | Splice Site (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- OR8G1 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OSBPL8 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 110/232 reads (47%) | called by muse, mutect2, varscan2
- PAN3 | c.1790G>A p.W597* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- PHF20L1 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLK | c.71A>C p.N24T | Missense Mutation (SNP) | VAF 98/182 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PRKCD | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPL35 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- SLC43A1 | c.1229A>G p.Y410C | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SRRD | c.55_70del p.K19Lfs*60 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- TNFRSF10B | c.1109T>C p.V370A | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- UBA6 | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AL451106.1 | c.108A>C p.V36= | Silent (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- CENPC | c.2721T>A p.P907= | Silent (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- DLG3 | c.297C>T p.N99= | Silent (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- DMD | c.9594T>C p.S3198= | Silent (SNP) | VAF 81/170 reads (48%) | called by muse, mutect2, varscan2
- DNAH5 | c.8391T>G p.L2797= | Silent (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- IGHV4-34 | c.322C>T p.L108= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs374573009; called by muse, mutect2, varscan2
- IGHV4-34 | c.162C>G p.S54= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as rs772068650; called by muse, mutect2, varscan2
- IQCE | c.201T>C p.P67= | Silent (SNP) | VAF 75/151 reads (50%) | catalogued as rs1377611809; called by muse, mutect2, varscan2
- KRT10 | c.177T>C p.R59= | Silent (SNP) | VAF 94/190 reads (49%) | called by muse, mutect2, varscan2
- LTBP4 | c.4587C>T p.Y1529= (on ENST00000308370 / NM_001042544.1; = p.Y1492= on NM_003573.2) | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as rs765337398; called by muse, mutect2, varscan2
- MSLN | c.1068G>A p.L356= | Silent (SNP) | VAF 63/134 reads (47%) | catalogued as rs1288055015; called by muse, mutect2, varscan2
- PIK3C2B | c.2307T>C p.S769= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2
- RNASE13 | c.462G>A p.S154= | Silent (SNP) | VAF 95/216 reads (44%) | catalogued as rs199616382, COSV100409536; called by muse, mutect2, varscan2
- UBA5 | c.237A>C p.V79= | Silent (SNP) | VAF 81/294 reads (28%) | called by muse, mutect2, varscan2
- UNC5D | c.192T>C p.Y64= | Silent (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- ZCCHC18 | c.864A>T p.S288= | Silent (SNP) | VAF 50/88 reads (57%) | called by muse, mutect2, varscan2
- ZDBF2 | c.2529C>T p.H843= | Silent (SNP) | VAF 64/122 reads (52%) | called by muse, mutect2, varscan2
- AC027612.1 | n.509G>T | RNA (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- ADRA2B | c.*9G>A | 3'UTR (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- AFF2 | c.*1768C>A | 3'UTR (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825896 A>G | 5'Flank (SNP) | VAF 54/119 reads (45%) | catalogued as rs371596555; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501811 A>G | 5'Flank (SNP) | VAF 28/77 reads (36%) | catalogued as rs754840353; called by muse, mutect2, varscan2
- ASRGL1 | c.190+98T>C | Intron (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- BBS2 | c.1797+28G>A | Intron (SNP) | VAF 32/80 reads (40%) | catalogued as rs1311625873; called by muse, mutect2, varscan2
- BMPER | c.*2154C>T | 3'UTR (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- CALB1 | c.*484C>G | 3'UTR (SNP) | VAF 48/102 reads (47%) | called by muse, mutect2, varscan2
- CALCRL | c.*1149G>A | 3'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- CDX4 | c.*256A>T | 3'UTR (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- CENPC | c.2761+116T>A | Intron (SNP) | VAF 14/24 reads (58%) | called by muse, varscan2
- CHRM3 | c.*5511A>C | 3'UTR (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- CHRNA7 | c.240+108A>C | Intron (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- COL18A1 | c.3929-62A>G | Intron (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- CTSZ | c.*451G>C | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2
- FAM43A | c.*446T>A | 3'UTR (SNP) | VAF 9/99 reads (9%) | catalogued as rs778294794, COSV61672599; called by muse, mutect2
- FLRT2 | c.-235A>C | 5'UTR (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- FOXL2NB | c.*1313G>T | 3'UTR (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- GALNT13 | c.*2489A>C | 3'UTR (SNP) | VAF 64/133 reads (48%) | called by muse, mutect2, varscan2
- GNL3 | c.72+43A>C | Intron (SNP) | VAF 193/203 reads (95%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1085-545T>C | Intron (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- H4-16 | c.*13G>A | 3'UTR (SNP) | VAF 57/129 reads (44%) | catalogued as COSV100797691; called by muse, mutect2, varscan2
- IFNB1 | c.*138A>G | 3'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- KRT18 | c.*34G>A | 3'UTR (SNP) | VAF 61/150 reads (41%) | called by muse, mutect2, varscan2
- LIN52 | c.*1662A>G | 3'UTR (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- LMO2 | c.*151A>G | 3'UTR (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- LRRC75A | c.*237C>T | 3'UTR (SNP) | VAF 38/64 reads (59%) | catalogued as rs1273349985; called by muse, mutect2, varscan2
- MARF1 | c.*746G>A | 3'UTR (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- MGAM | c.4619-10078A>T | Intron (SNP) | VAF 27/182 reads (15%) | called by muse, mutect2, varscan2
- MYCL | c.*1612del | 3'UTR (DEL) | VAF 47/105 reads (45%) | called by mutect2, pindel, varscan2
- MYO1F | c.1269+78C>G | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2
- NFIA | c.*7371T>A | 3'UTR (SNP) | VAF 25/39 reads (64%) | called by muse, mutect2, varscan2
- NRP2 | c.*2820T>A | 3'UTR (SNP) | VAF 24/43 reads (56%) | called by muse, mutect2, varscan2
- OR2T32P | n.927A>C | RNA (SNP) | VAF 95/186 reads (51%) | called by muse, mutect2, varscan2
- PSD3 | c.*120A>T | 3'UTR (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- PTPN1 | c.*415T>C | 3'UTR (SNP) | VAF 53/111 reads (48%) | catalogued as rs907661056; called by muse, mutect2, varscan2
- RAB30 | chr11:82980033 G>A | 3'Flank (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2, varscan2
- RELT | c.*749G>A | 3'UTR (SNP) | VAF 38/81 reads (47%) | catalogued as rs1216091142; called by muse, mutect2, varscan2
- SGK1 | c.153-72A>G | Intron (SNP) | VAF 9/9 reads (100%) | called by muse, mutect2, varscan2
- SLC29A1 | c.-162+1868C>T | Intron (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- SMIM13 | chr6:11138507 C>T | 3'Flank (SNP) | VAF 56/109 reads (51%) | called by muse, mutect2, varscan2
- SNORD116-18 | chr15:25090121 G>A | 3'Flank (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- ST20-MTHFS | chr15:79923880 A>C | 5'Flank (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- TECTB | c.*756A>G | 3'UTR (SNP) | VAF 55/116 reads (47%) | catalogued as rs1254686237; called by muse, mutect2, varscan2
- TELO2 | c.2126+155G>C | Intron (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2
- TGFBR2 | c.*319del | 3'UTR (DEL) | VAF 13/24 reads (54%) | called by muse*, mutect2, varscan2*
- TRPM3 | chr9:70535702 C>T | 3'Flank (SNP) | VAF 74/164 reads (45%) | catalogued as rs1046076061; called by muse, mutect2, varscan2
- TRPM7 | c.*82T>C | 3'UTR (SNP) | VAF 92/176 reads (52%) | called by muse, mutect2, varscan2
- ZBTB10 | c.*4476T>C | 3'UTR (SNP) | VAF 34/86 reads (40%) | called by muse, mutect2, varscan2
- ZNF875 | chr19:37334626 T>G | 5'Flank (SNP) | VAF 58/102 reads (57%) | called by muse, mutect2, varscan2
